Gene-level copy-number profile of specimen HCM-BROD-0047-C71-85B from HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee7124c0-ca74-4260-abd5-0d166f396ab3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0047-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/9291bd97-fcbc-4771-90ab-350741dbf6d9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 24,440; copy number 2: 27,302; copy number 3: 5,341; copy number 4: 710; copy number 5: 557; copy number 6: 42.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:84,545,131–84,640,565, 2 genes (within-gene range 0–1): HNRNPA1P72, AP000852.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 599 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,466,249–33,512,743, 3 genes, copy number 5: TLR12P, ZSCAN20, AC115285.1.
- chr5:95,555,101–95,605,102, 1 gene, copy number 5: ARSK.
- chr5:96,760,810–96,808,100, 3 genes, copy number 5 (within-gene range 4–5): ERAP1, AC008906.1, AC008906.2.
- chr7:118,184,144–129,169,699, 163 genes, copy number 5 (within-gene range 4–6) (broad region; genes not listed).
- chr7:129,225,023–138,442,238, 159 genes, copy number 5–6 (broad region; genes not listed).
- chr7:138,706,294–140,673,993, 42 genes, copy number 5–6 (within-gene range 4–6): ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1.
- chr7:140,719,327–142,933,746, 131 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:143,062,330–144,356,181, 70 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:145,005,058–148,420,998, 14 genes, copy number 5 (within-gene range 4–5): EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr7:147,831,770–148,801,110, 13 genes, copy number 5: RNU6-1184P, RNA5SP249, RN7SL456P, U3, RN7SL72P, AC083849.1, AC005229.2, AC005229.5, C7orf33, AC005229.1, AC005229.3, AC005229.4, CUL1.

Autosomal genes at a single copy (total copy number 1): 22,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
